Somatic mutation profile of tumor specimen TCGA-06-0882-01A (aliquot TCGA-06-0882-01A-01D-1492-08) from TCGA case TCGA-06-0882, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 30.4 years (11,112 days).
Specimen TCGA-06-0882-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52843d0a-e9a8-4fdb-a5e2-7c7f69ec5195.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0882-10A (Blood Derived Normal), aliquot TCGA-06-0882-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8b91887-6067-409a-a9c3-f40d84f7a1fb

The open-access MAF lists 38 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 23, Silent 11, Nonsense Mutation 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 56/169 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs121913294, CM074465, CM102472, COSV100911374, COSV64288961, COSV64302184; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARMC3 | c.1979A>G p.K660R | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV53059094; called by muse, mutect2, varscan2
- CEMIP2 | c.722C>T p.T241M | Missense Mutation (SNP) | VAF 40/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765559880, COSV65486383; called by muse, mutect2, varscan2
- CNTN6 | c.2696A>G p.K899R | Missense Mutation (SNP) | VAF 56/229 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs143460057, COSV63189935; called by muse, mutect2, varscan2
- COL4A4 | c.2918C>T p.T973I | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1466685743, COSV61630778; called by muse, mutect2
- CPS1 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104373018, COSV51805872; called by muse, mutect2, varscan2
- DRG2 | c.910A>T p.T304S | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52754399; called by muse, varscan2
- HELT | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV58819791; called by muse, mutect2, varscan2
- HOXB9 | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as COSV60816887; called by muse, varscan2
- ITGB7 | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as rs755050035, COSV57238189; called by muse, mutect2, varscan2
- KDM1B | c.1991C>A p.A664D (on ENST00000449850; = p.A431D on NM_153042.4) | Missense Mutation (SNP) | VAF 116/517 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV52809434; called by muse, mutect2, varscan2
- KDR | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV55761453; called by muse, mutect2, varscan2
- KIF19 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as rs952875372, COSV63429147; called by muse, mutect2, varscan2
- LEXM | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs201728919; called by muse, mutect2, varscan2
- MEGF8 | c.4843G>A p.V1615M (on ENST00000251268 / NM_001271938.2; = p.V1548M on NM_001410.3) | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs1054502372, COSV52079272; called by muse, mutect2, varscan2
- MID2 | c.1380G>T p.E460D | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.585); catalogued as COSV53307977; called by muse, mutect2
- OTOF | c.5027G>A p.R1676H (on ENST00000272371 / NM_194248.3; = p.R909H on NM_004802.4) | Missense Mutation (SNP) | VAF 65/293 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as rs143889717; called by muse, mutect2, varscan2
- PLCB2 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs761699247, COSV53031981; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3184T>G p.L1062V | Missense Mutation (SNP) | VAF 43/188 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100741292, COSV62782993; called by muse, mutect2, varscan2
- REM1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199660041, COSV52427586; called by muse, mutect2, varscan2
- SETBP1 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs146321232, COSV99952004; called by muse, mutect2, varscan2
- TDRD9 | c.3277T>C p.S1093P | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59144653; called by muse, mutect2
- TIGD3 | c.1260C>G p.D420E | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52888379; called by muse, mutect2, varscan2
- TRPM2 | c.2861C>A p.A954D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55967800; called by muse, mutect2, varscan2
- VPS52 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 57/247 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs750864533, COSV71403436; called by muse, mutect2, varscan2
- DENND2B | c.671del p.G224Afs*5 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | called by mutect2, pindel, varscan2
- NOBOX | c.1096_1099del p.N366Gfs*53 | Frame Shift Del (DEL) | VAF 6/40 reads (15%) | called by mutect2, pindel
- ABCC1 | c.3930C>T p.L1310= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as rs767559768, COSV60682899; called by muse, mutect2
- CARMIL2 | c.1701C>T p.D567= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1251896133, COSV58024556; called by muse, mutect2, varscan2
- DUXA | c.339A>G p.L113= | Silent (SNP) | VAF 47/173 reads (27%) | catalogued as rs747050180, COSV73729572; called by muse, mutect2, varscan2
- GRM8 | c.2637C>T p.G879= | Silent (SNP) | VAF 67/314 reads (21%) | catalogued as rs762951215, COSV58814787; called by muse, varscan2
- LAMA1 | c.6075G>A p.T2025= | Silent (SNP) | VAF 42/157 reads (27%) | catalogued as rs766719038, COSV67534312; called by muse, mutect2, varscan2
- LHFPL6 | c.72C>T p.C24= | Silent (SNP) | VAF 60/208 reads (29%) | catalogued as rs774101101, COSV65444620; called by muse, mutect2, varscan2
- LYZL6 | c.405C>A p.G135= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as rs1568418159; called by muse, mutect2, varscan2
- PAPPA2 | c.2583T>C p.T861= | Silent (SNP) | VAF 54/237 reads (23%) | catalogued as COSV62775557; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1584C>T p.S528= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as COSV54759039; called by muse, mutect2, varscan2
- RPAP1 | c.4014A>G p.T1338= | Silent (SNP) | VAF 147/525 reads (28%) | catalogued as rs755165863, COSV55489876; called by muse, mutect2, varscan2
- STAB1 | c.2361C>T p.V787= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as COSV58734001; called by muse, mutect2, varscan2
